Somatic mutation profile of tumor specimen TCGA-97-A4M0-01A (aliquot TCGA-97-A4M0-01A-11D-A24P-08) from TCGA case TCGA-97-A4M0, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.8 years (22,206 days).
Specimen TCGA-97-A4M0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3ce02f8-cce9-40c0-bc0b-08f04007c95e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-A4M0-10A (Blood Derived Normal), aliquot TCGA-97-A4M0-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0e5f8aa-e144-4030-9b53-79783e53003f

The open-access MAF lists 418 somatic variants for this specimen: 311 protein-altering or splice-affecting, 98 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 270, Silent 98, Nonsense Mutation 22, Frame Shift Del 10, Splice Site 8, RNA 5, Intron 2, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- SLC12A3 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121909383, CM961286, COSV99344704; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2845A>T p.S949C (on ENST00000272895 / NM_173076.3; = p.S631C on NM_015657.3) | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99791884; called by muse, mutect2, varscan2
- ACOX1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs762248481, COSV99503969; called by muse, mutect2, varscan2
- ACTB | c.803-2A>T p.X268_splice | Splice Site (SNP) | VAF 64/180 reads (36%) | catalogued as COSV100079936; called by muse, mutect2, varscan2
- ACTN2 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs148972050, COSV100856986; called by muse, mutect2, varscan2
- ADAM28 | c.1783C>A p.Q595K | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.171); catalogued as COSV99739779; called by muse, mutect2, varscan2
- ADAMTS19 | c.1477A>T p.N493Y | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99180562; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.334); catalogued as COSV99721094; called by muse, mutect2, varscan2
- ADCY2 | c.3226G>C p.V1076L | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); catalogued as COSV100604063; called by muse, mutect2
- ADGRE1 | c.2480A>T p.Y827F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV99165826; called by muse, mutect2, varscan2
- ADIG | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100972558; called by muse, mutect2, varscan2
- ADIPOR1 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV100579655; called by muse, mutect2, varscan2
- AGTR1 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs1481397980, COSV100837185; called by muse, mutect2, varscan2
- AGXT2 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51484087, COSV51490592, COSV99183908; called by muse, mutect2, varscan2
- AKAP4 | c.1259C>A p.T420K | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100654361; called by muse, mutect2, varscan2
- APMAP | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99469040; called by muse, mutect2, varscan2
- ARAP3 | c.1343A>G p.K448R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs752644776, COSV99500257; called by muse, mutect2, varscan2
- ARHGAP25 | c.1597G>A p.A533T (on ENST00000409202 / NM_001007231.3; = p.A525T on NM_014882.3) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99772079; called by muse, mutect2, varscan2
- ARHGAP30 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100920494; called by muse, mutect2, varscan2
- ARHGEF6 | c.1539C>A p.D513E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51692397; called by muse, mutect2, varscan2
- ARL4A | c.21C>G p.D7E | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100775967; called by muse, mutect2, varscan2
- ASXL3 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV52464911, COSV52466526; called by muse, mutect2, varscan2
- ATP2B2 | c.3280C>A p.P1094T (on ENST00000352432; = p.P1060T on NM_001683.5) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.24); catalogued as COSV100660450; called by muse, mutect2, varscan2
- BAP1 | c.254A>G p.Q85R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56232001, COSV56233725; called by muse, mutect2, varscan2
- BBS7 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as COSV99145088; called by muse, mutect2, varscan2
- BRDT | c.1847G>T p.R616I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100746581, COSV62865516; called by muse, mutect2, varscan2
- BTN1A1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs374903527; called by muse, mutect2, varscan2
- CACNA1A | c.5022C>G p.I1674M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100803173; called by muse, mutect2, varscan2
- CACNA2D1 | c.2971A>T p.S991C (on ENST00000356253 / NM_001366867.1; = p.S979C on NM_000722.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100667255; called by muse, mutect2, varscan2
- CACNG3 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs747446701, COSV99137078; called by muse, mutect2, varscan2
- CALCR | c.826C>T p.R276W (on ENST00000649521 / NM_001164737.2; = p.R260W on NM_001742.4) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs144902080; called by muse, mutect2, varscan2
- CASP5 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); catalogued as COSV52832361, COSV99508074; called by muse, mutect2, varscan2
- CAVIN4 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100293392; called by muse, mutect2, varscan2
- CBWD2 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV99380809; called by mutect2, varscan2
- CCDC150 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV99777359; called by muse, mutect2, varscan2
- CDC14A | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); catalogued as rs371468460, COSV100325925; called by muse, mutect2, varscan2
- CDX4 | c.579T>A p.H193Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100999155; called by muse, mutect2, varscan2
- CFAP65 | c.1428G>T p.W476C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV99838446; called by muse, mutect2, varscan2
- CFH | c.2329A>T p.I777L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV100810145; called by muse, mutect2, varscan2
- CHCHD4 | c.370G>A p.A124T (on ENST00000396914 / NM_001098502.2; = p.A137T on NM_144636.3) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV99853993; called by muse, mutect2, varscan2
- CHPT1 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57533968, COSV99977855; called by muse, mutect2, varscan2
- CLEC4M | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99940824; called by muse, mutect2, varscan2
- CNDP2 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100159275, COSV60838909; called by muse, mutect2, varscan2
- CNKSR1 | c.1480G>T p.V494L (on ENST00000374253 / NM_001297647.2; = p.V487L on NM_006314.3) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100128513; called by muse, mutect2, varscan2
- COL11A1 | c.4056G>T p.E1352D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1306769069, COSV100615182, COSV100617983; called by muse, mutect2, varscan2
- CORIN | c.2874C>A p.Y958* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99904422; called by muse, mutect2, varscan2
- COX10 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99887050; called by muse, mutect2, varscan2
- CPXCR1 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99341898; called by muse, mutect2
- CRB1 | c.1971C>A p.N657K | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV100958075; called by muse, mutect2, varscan2
- CRB1 | c.2240A>T p.Q747L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100958076; called by muse, mutect2, varscan2
- CREB5 | c.945C>A p.H315Q (on ENST00000357727 / NM_182898.4; = p.H308Q on NM_004904.3) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV100745462; called by muse, mutect2, varscan2
- CSMD3 | c.10525G>T p.G3509* (on ENST00000297405 / NM_001363185.1; = p.G3340* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99846951; called by muse, mutect2, varscan2
- CSMD3 | c.6442G>T p.G2148C (on ENST00000297405 / NM_001363185.1; = p.G2044C on NM_052900.3) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99846954; called by muse, mutect2, varscan2
- CSMD3 | c.2273G>A p.R758Q (on ENST00000297405 / NM_001363185.1; = p.R654Q on NM_052900.3) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1286397306, COSV52093344; called by muse, mutect2, varscan2
- CSMD3 | c.1705G>T p.D569Y (on ENST00000297405 / NM_001363185.1; = p.D465Y on NM_052900.3) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99829795, COSV99846956; called by muse, mutect2, varscan2
- CSMD3 | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99846958; called by muse, mutect2, varscan2
- CTSG | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as COSV99361689; called by muse, mutect2, varscan2
- CYP11B1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99455679; called by muse, mutect2, varscan2
- CYRIB | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101310351; called by muse, mutect2, varscan2
- DCAF12L1 | c.984C>A p.H328Q | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV100948442, COSV64421442; called by muse, mutect2, varscan2
- DCTN1 | c.2195G>A p.S732N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV62620871; called by muse, mutect2, varscan2
- DDHD1 | c.1250A>T p.K417M (on ENST00000323669; = p.K614M on NM_030637.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100080035; called by muse, mutect2
- DMD | c.6212G>A p.R2071K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs774825173, COSV100822616; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK11 | c.3445G>T p.A1149S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV99354687; called by muse, mutect2, varscan2
- DOCK2 | c.2428T>G p.F810V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99915229; called by muse, mutect2, varscan2
- DQX1 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs376450262, COSV101099221; called by muse, mutect2, varscan2
- DRP2 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100872060; called by muse, mutect2, varscan2
- DSCAML1 | c.4471G>T p.V1491L (on ENST00000321322; = p.V1431L on NM_020693.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100357176; called by muse, mutect2, varscan2
- DST | c.2243T>A p.L748H (on ENST00000361203 / NM_001374722.1; = p.L422H on NM_001723.6) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99759762; called by muse, mutect2, varscan2
- DUSP5 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100851938; called by muse, mutect2, varscan2
- DYRK4 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747416114, COSV99157999; called by muse, mutect2, varscan2
- EEF1A2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs760330590, COSV99419869; called by muse, mutect2, varscan2
- EEF2 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100500978; called by muse, mutect2, varscan2
- ELAPOR1 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100884477; called by muse, mutect2
- ENPP3 | c.1851G>C p.Q617H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100718038; called by muse, mutect2, varscan2
- EPB41L4A | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99814084; called by muse, mutect2, varscan2
- EPHA5 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV99901126; called by muse, mutect2, varscan2
- EPHX2 | c.946-1G>T p.X316_splice | Splice Site (SNP) | VAF 40/84 reads (48%) | catalogued as COSV100994808; called by muse, mutect2, varscan2
- ERICH3 | c.2041G>C p.A681P | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58623113; called by muse, mutect2, varscan2
- EXOC2 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 25/139 reads (18%) | catalogued as COSV100034202; called by muse, mutect2, varscan2
- EXOG | c.579G>T p.W193C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV99815499; called by muse, mutect2, varscan2
- EYA3 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV100870296; called by muse, mutect2, varscan2
- FAM120A | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99466582; called by muse, mutect2, varscan2
- FAM135A | c.4142A>G p.K1381R (on ENST00000370479 / NM_001351599.1; = p.K1168R on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99526634; called by muse, mutect2, varscan2
- FAM216B | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV100573094; called by muse, mutect2, varscan2
- FAT3 | c.7354A>G p.T2452A | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV99970759; called by muse, mutect2, varscan2
- FAT3 | c.11190G>C p.E3730D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99970760; called by muse, mutect2, varscan2
- FBXO16 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100672462; called by muse, mutect2, varscan2
- FBXW11 | c.789+1G>T p.X263_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99441450; called by muse, mutect2, varscan2
- FERD3L | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as COSV51763727, COSV99285087; called by muse, mutect2, varscan2
- FLG2 | c.4634G>A p.G1545E | Missense Mutation (SNP) | VAF 241/499 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV101166208; called by muse, mutect2, varscan2
- FRY | c.2133C>A p.N711K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100969891; called by muse, mutect2
- FRZB | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.177); catalogued as COSV99717547; called by muse, mutect2, varscan2
- FSIP2 | c.18524C>A p.S6175Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100556417; called by muse, mutect2
- FUBP1 | c.925A>T p.I309F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99629581; called by muse, mutect2, varscan2
- G6PD | c.1365C>A p.S455R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as COSV100855132; called by muse, mutect2, varscan2
- GABRA2 | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as COSV62916281; called by muse, mutect2, varscan2
- GABRB3 | c.760T>A p.S254T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV100161698; called by muse, mutect2, varscan2
- GATA1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64963024; called by muse, mutect2, varscan2
- GBP4 | c.1292A>T p.H431L | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100864461; called by muse, mutect2, varscan2
- GFI1B | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100254442; called by muse, mutect2, varscan2
- GFPT2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99518071; called by muse, mutect2
- GLT1D1 | c.778G>T p.E260* (on ENST00000442111 / NM_001366889.1; = p.E180* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs1278855460, COSV55887551, COSV99897584; called by muse, mutect2, varscan2
- GPR119 | c.713G>T p.W238L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358714; called by muse, mutect2, varscan2
- GPR6 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51572713, COSV99254541; called by muse, mutect2, varscan2
- GREB1 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99303762; called by muse, mutect2, varscan2
- GRHL1 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258158; called by muse, mutect2, varscan2
- GRIA3 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.819); catalogued as COSV99990418, COSV99991660; called by muse, mutect2, varscan2
- GRIK2 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV100029253; called by muse, mutect2
- H3C11 | c.395G>C p.R132P | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV58899761, COSV58901148; called by muse, mutect2, varscan2
- HAPLN4 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as COSV99364021; called by muse, mutect2, varscan2
- HAUS5 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99178818; called by muse, mutect2
- HERC1 | c.12940G>A p.A4314T | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV101496889; called by muse, mutect2, varscan2
- HERC2 | c.3928G>T p.G1310C | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99876617; called by muse, mutect2, varscan2
- HNRNPL | c.1179G>C p.K393N | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99670550; called by muse, mutect2, varscan2
- HOXD9 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99982338; called by muse, mutect2, varscan2
- HS3ST4 | c.1299A>T p.K433N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs369043728, COSV58801696; called by muse, mutect2, varscan2
- IDH3G | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV99473417; called by muse, mutect2, varscan2
- IGF2BP3 | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99325821; called by muse, mutect2, varscan2
- IL12RB2 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99255635; called by muse, mutect2
- IL17RC | c.862G>A p.D288N (on ENST00000295981 / NM_153461.4; = p.D202N on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99926005; called by muse, mutect2, varscan2
- IL18R1 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV99295483; called by muse, mutect2, varscan2
- IMPG2 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99516457; called by muse, mutect2, varscan2
- INTS6L | c.190-1G>T p.X64_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100878299; called by muse, mutect2, varscan2
- IQCG | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 55/162 reads (34%) | catalogued as COSV54566247, COSV99502690; called by muse, mutect2, varscan2
- ITPR2 | c.5888G>T p.C1963F | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190156; called by muse, mutect2, varscan2
- ITPR3 | c.5113del p.D1705Tfs*6 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | catalogued as rs753781307; called by mutect2, pindel, varscan2
- JAKMIP3 | c.2331G>T p.Q777H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100059887; called by muse, mutect2, varscan2
- KAT2A | c.1785G>A p.M595I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288493; called by muse, mutect2, varscan2
- KCND3 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV100138403; called by muse, mutect2, varscan2
- KCNG4 | c.1249A>T p.T417S | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377172; called by muse, mutect2, varscan2
- KDR | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.659); catalogued as COSV99818582, COSV99818918; called by muse, mutect2, varscan2
- KIAA1210 | c.2167C>A p.Q723K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs760215525, COSV101274384; called by muse, mutect2, varscan2
- KIF2B | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99276177, COSV99276233; called by muse, mutect2, varscan2
- KIF2C | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV100945860; called by muse, mutect2, varscan2
- KMT2D | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99985601; called by muse, mutect2, varscan2
- KRT1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99358992; called by muse, mutect2, varscan2
- KRT14 | c.702C>A p.D234E | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99391165; called by muse, mutect2, varscan2
- KRT5 | c.209del p.G70Afs*81 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | catalogued as rs1565594174, COSV52862340; called by pindel, varscan2
- KRT80 | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV100502903; called by muse, mutect2, varscan2
- LRRC4C | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV53426395, COSV99539654; called by muse, mutect2, varscan2
- LRRC66 | c.1841G>T p.W614L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100603096; called by muse, mutect2, varscan2
- LRRC7 | c.2895A>T p.K965N (on ENST00000651989 / NM_001370785.2; = p.K932N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99229622; called by muse, mutect2, varscan2
- MAGEB2 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100975749; called by muse, mutect2, varscan2
- MAP3K15 | c.3403C>A p.L1135I | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100135662; called by muse, mutect2, varscan2
- MAP3K8 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV99552333; called by muse, mutect2, varscan2
- MCAT | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV99295772; called by muse, mutect2, varscan2
- MED7 | c.668G>A p.C223Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99644317; called by muse, mutect2, varscan2
- MGAM | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV101527740; called by muse, mutect2, varscan2
- MICAL3 | c.4604A>T p.E1535V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV101490962; called by muse, mutect2, varscan2
- MKI67 | c.6928G>T p.A2310S | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.806); catalogued as COSV100896968, COSV64076483; called by muse, mutect2, varscan2
- MPEG1 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV99915927; called by muse, mutect2, varscan2
- MPL | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV65245605; called by muse, mutect2, varscan2
- MRM2 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV99642771; called by muse, mutect2, varscan2
- MTM1 | c.529-1G>T p.X177_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as CS123809, COSV100080556; called by muse, varscan2
- MTM1 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100080437, COSV100080671; called by muse, mutect2, varscan2
- MVK | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as CM115597, CM990889, COSV57332161, COSV99950108; called by muse, mutect2, varscan2
- MYH15 | c.2201A>C p.Y734S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56305403, COSV99844267; called by muse, varscan2
- MYPN | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100590594; called by muse, mutect2, varscan2
- NAA16 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV101038413; called by muse, mutect2, varscan2
- NAV1 | c.5158C>T p.P1720S | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1176141534, COSV99819631; called by muse, mutect2, varscan2
- NCCRP1 | c.688-1G>C p.X230_splice | Splice Site (SNP) | VAF 56/185 reads (30%) | catalogued as COSV100355888; called by muse, mutect2
- NEUROD6 | c.407T>C p.L136S | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99774191; called by muse, mutect2, varscan2
- NFYB | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99527267; called by muse, mutect2, varscan2
- NHS | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101196960; called by muse, mutect2, varscan2
- NKX2-5 | c.547A>C p.K183Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234900; called by muse, mutect2, varscan2
- NLK | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV101311356; called by muse, mutect2, varscan2
- NLRP3 | c.2434G>T p.G812* | Nonsense Mutation (SNP) | VAF 74/146 reads (51%) | catalogued as COSV100276624; called by muse, mutect2, varscan2
- NOTCH1 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1216073441, COSV53071829, COSV53072814; called by muse, mutect2, varscan2
- NOTCH2 | c.5119G>T p.G1707C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99866666; called by muse, mutect2, varscan2
- NR2F6 | c.1144A>G p.I382V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs765130843, COSV99285829; called by muse, mutect2, varscan2
- NRSN1 | c.130T>A p.Y44N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.226); catalogued as COSV101027371; called by muse, mutect2, varscan2
- NSMAF | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs775851258, COSV99233433; called by muse, mutect2, varscan2
- NSMCE4A | c.478A>G p.M160V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs892350531, COSV100940091; called by muse, mutect2, varscan2
- NTNG1 | c.1543G>T p.G515C (on ENST00000370068 / NM_001113226.3; = p.G414C on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.503); catalogued as rs1235580054, COSV100903815; called by muse, mutect2, varscan2
- NUP98 | c.4414G>T p.E1472* (on ENST00000359171 / NM_001365126.1; = p.E1455* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100263421; called by muse, mutect2, varscan2
- OBSCN | c.3409G>T p.G1137C | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99484045; called by muse, mutect2, varscan2
- OLFM4 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV54578720, COSV99524558; called by muse, mutect2
- OR10H2 | c.26T>A p.M9K | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100008882; called by muse, mutect2, varscan2
- OR2G2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100189977; called by muse, mutect2, varscan2
- OR2L8 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 194/410 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100594306; called by muse, mutect2, varscan2
- OR2L8 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100594307; called by muse, mutect2, varscan2
- OR4C6 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100051846; called by muse, mutect2, varscan2
- OR52N4 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs754034580, COSV100421755; called by muse, mutect2, varscan2
- OR7G1 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV99528789; called by muse, mutect2, varscan2
- OR8B4 | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV100635871, COSV62069747; called by muse, mutect2, varscan2
- OVCH1 | c.2807C>A p.P936Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs759821156, COSV100549183; called by muse, mutect2, varscan2
- OVCH1 | c.1257T>A p.C419* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100549184; called by muse, mutect2, varscan2
- PAWR | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as COSV100174407; called by muse, mutect2, varscan2
- PCDHA2 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100974136; called by muse, mutect2, varscan2
- PCDHB1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60631849; called by muse, mutect2, varscan2
- PCDHGA10 | c.2169G>T p.W723C | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV99546452; called by muse, mutect2, varscan2
- PDE8A | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100052336; called by muse, mutect2, varscan2
- PDGFRA | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as rs761446758, COSV57267141, COSV99957581; ClinVar: uncertain significance; called by muse, mutect2
- PHF3 | c.3025C>T p.H1009Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV100013949; called by muse, mutect2, varscan2
- PHLDA3 | c.246G>C p.E82D | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100943650; called by muse, mutect2, varscan2
- PIP4P2 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99575600; called by muse, mutect2
- PIP5KL1 | c.908G>T p.R303L (on ENST00000388747 / NM_001135219.2; = p.R100L on NM_173492.1) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.349); catalogued as COSV100304956; called by muse, mutect2, varscan2
- PJA1 | c.1364C>A p.S455Y (on ENST00000361478 / NM_145119.4; = p.S267Y on NM_022368.5) | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV100824806, COSV64053521; called by muse, mutect2, varscan2
- PKD2L2 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99296680; called by muse, mutect2, varscan2
- PKP2 | c.224-2A>T p.X75_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99298462; called by muse, mutect2
- PLCXD3 | c.323A>T p.N108I | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100126316, COSV60621871; called by muse, mutect2, varscan2
- POM121L12 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV68693534, COSV68694306; called by muse, mutect2, varscan2
- POU5F2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67938511; called by muse, mutect2, varscan2
- PPP6R3 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99677440; called by muse, mutect2, varscan2
- PRAMEF12 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.287); catalogued as COSV100742978; called by muse, mutect2
- PRDM14 | c.1339C>A p.L447I | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99400502; called by muse, mutect2, varscan2
- PRDM4 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99946720; called by muse, mutect2, varscan2
- PRIM1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590474; called by muse, mutect2, varscan2
- PRKD1 | c.945A>T p.K315N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV100121475; called by muse, mutect2, varscan2
- PRUNE2 | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV65038143; called by muse, mutect2, varscan2
- PSG2 | c.43T>C p.W15R | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV68884217; called by muse, mutect2, varscan2
- PSG7 | c.1241C>A p.S414Y | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV101343336; called by muse, mutect2, varscan2
- PTH2R | c.767T>A p.V256E | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99782867; called by muse, mutect2, varscan2
- PTPN11 | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100692857; called by muse, mutect2, varscan2
- PTPRZ1 | c.5365G>T p.D1789Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101100801, COSV66444240; called by muse, mutect2, varscan2
- PTPRZ1 | c.5496A>T p.K1832N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV101100802; called by muse, mutect2, varscan2
- QDPR | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99845947; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2207G>C p.G736A | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99770466; called by muse, mutect2, varscan2
- RABGGTB | c.197T>C p.M66T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV100175229; called by muse, mutect2, varscan2
- RASAL2 | c.977G>T p.R326I | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100862911; called by muse, mutect2, varscan2
- RDH11 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs756459888, COSV101191525; called by muse, mutect2, varscan2
- RFX4 | c.1769C>G p.P590R (on ENST00000392842 / NM_213594.3; = p.P496R on NM_032491.6) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99986324; called by muse, mutect2, varscan2
- RGPD2 | c.3961G>C p.E1321Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100553127; called by mutect2, varscan2
- RHNO1 | c.583G>T p.G195* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV100817079; called by muse, mutect2, varscan2
- RIMBP2 | c.1294G>C p.V432L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99900069, COSV99900431; called by muse, mutect2, varscan2
- RIMS2 | c.2576C>A p.S859* (on ENST00000666250 / NM_001348490.2; = p.S667* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99198583; called by muse, mutect2, varscan2
- RNF38 | c.896A>T p.Q299L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV99425342; called by muse, mutect2
- ROR1 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100935596; called by muse, mutect2, varscan2
- ROR2 | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as CM002097, COSV100996102; called by muse, mutect2, varscan2
- RPGR | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140427, COSV58836215; called by muse, mutect2, varscan2
- RTKN2 | c.1651C>G p.H551D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV100189610; called by muse, mutect2, varscan2
- RYR1 | c.1872G>T p.L624F | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616930; called by muse, mutect2, varscan2
- SBSN | c.1678G>T p.A560S (on ENST00000452271 / NM_001166034.2; = p.A217S on NM_198538.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV101510107; called by muse, mutect2, varscan2
- SCAF8 | c.1199C>G p.S400* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV65790621; called by muse, mutect2
- SCML2 | c.309A>C p.R103S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99319474; called by muse, mutect2, varscan2
- SCN10A | c.2536C>T p.L846F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101479533; called by muse, mutect2, varscan2
- SCN11A | c.4972C>A p.R1658S | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100182488; called by muse, mutect2, varscan2
- SDF2L1 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as COSV99963668; called by muse, varscan2
- SEC24A | c.1151+1G>A p.X384_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as rs1349887055, COSV100524677; called by muse, mutect2, varscan2
- SERPINB3 | c.1101C>A p.H367Q | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99380209; called by muse, mutect2, varscan2
- SH3BP5L | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100822097; called by muse, mutect2, varscan2
- SLC17A8 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as COSV100035850; called by muse, mutect2, varscan2
- SLC28A3 | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100883337; called by muse, mutect2, varscan2
- SLC7A13 | c.8G>T p.R3I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52537535, COSV99879201; called by muse, mutect2
- SLC7A14 | c.1591A>T p.I531F | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs768895376, COSV51592625; called by muse, mutect2, varscan2
- SLC9A6 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV100857950; called by muse, mutect2, varscan2
- SLC9B2 | c.1608A>T p.Q536H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100294300; called by muse, mutect2, varscan2
- SLITRK2 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100158193; called by muse, mutect2, varscan2
- SLITRK4 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100567516; called by muse, mutect2, varscan2
- SMARCA2 | c.1069A>T p.R357W | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100571508; called by muse, mutect2, varscan2
- SMG1 | c.6892A>G p.K2298E | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV101246784; called by muse, mutect2, varscan2
- SNRPA1 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99574477, COSV99574710; called by muse, mutect2, varscan2
- SOWAHB | c.1393C>G p.H465D | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100530797; called by muse, mutect2, varscan2
- SPATS2L | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100660874; called by muse, mutect2, varscan2
- SPTBN2 | c.1500G>T p.K500N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV100020438; called by muse, mutect2, varscan2
- SYPL2 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100881488; called by muse, mutect2, varscan2
- TAS2R1 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV101225863; called by muse, mutect2, varscan2
- TENM3 | c.5177C>T p.T1726I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV101305458; called by muse, mutect2, varscan2
- TENT5D | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382961; called by muse, mutect2, varscan2
- TEX13A | c.1109G>T p.R370I | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100781936; called by muse, mutect2, varscan2
- THUMPD2 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as COSV53186570; called by muse, mutect2, varscan2
- TM6SF1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99362871; called by muse, mutect2, varscan2
- TMEM200A | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99760068; called by muse, mutect2, varscan2
- TMEM248 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100447478; called by muse, mutect2, varscan2
- TMEM52 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs927368850, COSV100205676; called by muse, mutect2, varscan2
- TP53BP1 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.081); catalogued as rs1247584491, COSV99781454; called by muse, mutect2, varscan2
- TRAPPC11 | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as COSV100592040; called by muse, mutect2, varscan2
- TRHDE | c.1070G>T p.R357I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99672405; called by muse, mutect2, varscan2
- TRIM58 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100825283; called by muse, mutect2, varscan2
- TRO | c.3061A>T p.S1021C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99437282; called by muse, mutect2, varscan2
- TRPM3 | c.2455C>A p.P819T (on ENST00000357533 / NM_001366142.2; = p.P662T on NM_020952.6) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.244); catalogued as COSV100678667; called by muse, mutect2, varscan2
- TRPM8 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs776737159, COSV100224522; called by muse, mutect2, varscan2
- TSHZ2 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.203); catalogued as rs769563714, COSV100295964, COSV100296737; called by muse, mutect2, varscan2
- TSPAN31 | c.471C>A p.C157* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99224216; called by muse, mutect2, varscan2
- TSPYL2 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100212418; called by muse, mutect2, varscan2
- UBE2O | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100085027; called by muse, mutect2, varscan2
- USH2A | c.7367C>G p.S2456C | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100242274; called by muse, mutect2, varscan2
- UTRN | c.3733G>T p.E1245* | Nonsense Mutation (SNP) | VAF 50/133 reads (38%) | catalogued as COSV100840618; called by muse, mutect2, varscan2
- VPS13D | c.7939G>A p.E2647K | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV99167487, COSV99169351; called by muse, mutect2, varscan2
- VPS35L | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99221677; called by muse, mutect2, varscan2
- WNT10A | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as CM1411728, COSV99297581; called by muse, mutect2
- XRCC5 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.053); catalogued as COSV101079890; called by muse, mutect2, varscan2
- ZBTB43 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV100991467; called by muse, mutect2, varscan2
- ZDHHC8 | c.865G>T p.G289W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57712527; called by muse, mutect2, varscan2
- ZFPM2 | c.1733T>C p.M578T | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV101023532; called by muse, mutect2, varscan2
- ZMYM3 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.322); catalogued as COSV100078376, COSV58737427, COSV58737515; called by muse, mutect2, varscan2
- ZNF180 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552404861, COSV99660069; called by muse, mutect2, varscan2
- ZNF257 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101448163, COSV71306449, COSV71310253; called by muse, mutect2, varscan2
- ZNF300 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.564); catalogued as COSV51037048; called by muse, mutect2, varscan2
- ZNF423 | c.1268C>T p.S423F (on ENST00000563137 / NM_001379286.1; = p.S415F on NM_015069.4) | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as rs760242467, COSV52196635, COSV99283678; called by muse, mutect2, varscan2
- ZNF479 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100483049; called by muse, mutect2, varscan2
- ZNF518B | c.3180A>G p.I1060M | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100456876; called by muse, mutect2, varscan2
- ZNF74 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); catalogued as COSV100677553, COSV62624803; called by muse, mutect2, varscan2
- CDH9 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- FAAH | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- FAM47C | c.259del p.Q87Kfs*32 | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | called by mutect2, pindel, varscan2
- IGHV1-2 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV2D-24 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ITIH6 | c.2190del p.S731Qfs*9 | Frame Shift Del (DEL) | VAF 55/176 reads (31%) | called by mutect2, pindel, varscan2
- LAMA2 | c.1312del p.A438Hfs*14 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- MARK1 | c.727_728insA p.L243Hfs*43 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | called by mutect2, pindel*, varscan2
- NAV3 | c.2488del p.S830Vfs*12 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- PKD1 | c.7749del p.L2584Sfs*36 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- RBMXL2 | c.909_910del p.G304Rfs*59 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- TMEM255A | c.314del p.C105Ffs*4 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- TRAJ42 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- TRBV24-1 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TXNDC9 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- YTHDF1 | c.408del p.S137Lfs*44 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.924C>A p.L308= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100941847; called by muse, mutect2, varscan2
- ADAMTSL2 | c.249G>T p.P83= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs539727283, COSV100618828, COSV100619037; called by muse, mutect2, varscan2
- ADCY8 | c.3513G>T p.L1171= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV99654197; called by muse, mutect2, varscan2
- ADGRG4 | c.4518G>A p.T1506= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs773301806, COSV99795770; called by muse, mutect2, varscan2
- ADGRG7 | c.1869G>T p.P623= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV56295824, COSV99841520; called by muse, mutect2, varscan2
- ADGRL3 | c.3948G>T p.G1316= (on ENST00000506720 / NM_001322402.2; = p.G1205= on NM_015236.6) | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV72230743, COSV72231480; called by muse, mutect2, varscan2
- ADGRL4 | c.1956C>T p.S652= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100876094; called by muse, mutect2, varscan2
- ALLC | c.217C>A p.R73= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV52996902; called by muse, mutect2, varscan2
- ANKIB1 | c.2919C>T p.I973= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV56067060, COSV99729908; called by muse, mutect2, varscan2
- ARHGEF25 | c.1392C>A p.I464= | Silent (SNP) | VAF 42/143 reads (29%) | catalogued as COSV99678278; called by muse, mutect2, varscan2
- ATP6V0D2 | c.717C>G p.T239= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99572054; called by muse, mutect2, varscan2
- BAHCC1 | c.5046G>T p.V1682= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100312039; called by muse, mutect2, varscan2
- BCORL1 | c.3345G>C p.P1115= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV54401490, COSV99500865; called by muse, mutect2, varscan2
- C12orf40 | c.1281C>T p.N427= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100210752; called by muse, mutect2, varscan2
- CALN1 | c.348G>A p.G116= (on ENST00000329008 / NM_001017440.3; = p.G158= on NM_031468.4) | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV61154844; called by muse, mutect2, varscan2
- CAMKMT | c.786A>T p.P262= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV101035474; called by muse, mutect2, varscan2
- CCDC17 | c.1155C>T p.D385= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100601998; called by muse, mutect2
- CCDC74B | c.522T>A p.S174= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100134730; called by muse, mutect2, varscan2
- CCNB3 | c.744G>A p.S248= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs375491454, COSV99328817; called by muse, mutect2, varscan2
- CD276 | c.195C>T p.L65= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100573446; called by muse, mutect2, varscan2
- CD93 | c.907C>A p.R303= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99849559; called by muse, mutect2, varscan2
- CDC14B | c.261A>T p.A87= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99686240; called by muse, mutect2, varscan2
- CEACAM4 | c.324G>T p.L108= | Silent (SNP) | VAF 54/188 reads (29%) | catalogued as COSV99701213; called by muse, mutect2, varscan2
- CFAP47 | c.5214T>C p.C1738= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100545704; called by muse, mutect2, varscan2
- CHAD | c.672G>A p.L224= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV99366318; called by muse, mutect2, varscan2
- CLDN12 | c.555G>C p.L185= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as COSV99842227; called by muse, mutect2, varscan2
- CNGA2 | c.24G>A p.V8= | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as rs770792204, COSV61703141; called by muse, mutect2, varscan2
- CXorf21 | c.618T>G p.S206= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV100973358; called by muse, mutect2, varscan2
- CYP4F12 | c.9G>T p.L3= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs200916951; called by muse, mutect2, varscan2
- DCAF12L2 | c.840G>T p.V280= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100758834; called by muse, mutect2, varscan2
- DDRGK1 | c.783G>T p.V261= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100621528; called by muse, mutect2, varscan2
- DMD | c.9702G>T p.L3234= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100629213; called by muse, mutect2, varscan2
- DMXL1 | c.4128C>T p.I1376= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1237967825, COSV100224929; called by muse, mutect2, varscan2
- ERCC6 | c.684C>T p.L228= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100876190; called by muse, mutect2, varscan2
- EXOC6B | c.768A>T p.T256= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99726336; called by muse, mutect2, varscan2
- FLNA | c.4524C>G p.T1508= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100775219, COSV61049773; called by muse, mutect2, varscan2
- FRMD7 | c.1374C>T p.S458= | Silent (SNP) | VAF 99/279 reads (35%) | catalogued as rs138801659, COSV100049283; called by muse, mutect2, varscan2
- FRMPD2 | c.3240C>T p.V1080= | Silent (SNP) | VAF 7/25 reads (28%) | called by mutect2, varscan2
- GBA3 | c.276C>T p.I92= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV72438538; called by muse, mutect2, varscan2
- GJA8 | c.657C>T p.L219= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as COSV99569687; called by muse, mutect2, varscan2
- GRIK1 | c.777C>A p.T259= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs1279029753, COSV100517873; called by muse, mutect2, varscan2
- H3-4 | c.213G>A p.L71= | Silent (SNP) | VAF 101/198 reads (51%) | catalogued as COSV64211106; called by muse, mutect2, varscan2
- HMX2 | c.403C>A p.R135= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1191767377, COSV100378857; called by muse, mutect2, varscan2
- HNRNPH2 | c.639G>A p.P213= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs191816846, COSV99516588; called by muse, mutect2, varscan2
- IGKV3D-20 | c.285C>A p.T95= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- INS | c.297C>A p.I99= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV51747133; called by muse, mutect2, varscan2
- ITCH | c.2301G>A p.Q767= (on ENST00000262650 / NM_001257137.3; = p.Q726= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99393150; called by muse, mutect2, varscan2
- ITGA7 | c.771C>A p.R257= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99156243; called by muse, mutect2, varscan2
- KCNA4 | c.1821C>T p.D607= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100069248; called by muse, mutect2, varscan2
- KCNH5 | c.1794C>A p.I598= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV100528075; called by muse, mutect2, varscan2
- KIR2DL3 | c.15C>G p.V5= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs748497705, COSV52545491, COSV99400171; called by muse, mutect2, varscan2
- KIT | c.546C>G p.L182= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV99855272; called by muse, mutect2, varscan2
- MAGEC1 | c.3000G>C p.L1000= | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as COSV99596481; called by muse, mutect2, varscan2
- MAGT1 | c.372C>A p.G124= (on ENST00000618282 / NM_001367916.1; = p.G156= on NM_032121.5) | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100800439; called by muse, mutect2, varscan2
- MCOLN1 | c.363G>A p.T121= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as rs758222055, COSV51181585; called by muse, mutect2, varscan2
- MGAT4C | c.540A>T p.P180= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100153361; called by muse, mutect2, varscan2
- MUC6 | c.7044C>A p.V2348= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100173328; called by muse, mutect2
- MYO6 | c.1017G>C p.R339= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100889417, COSV64118143, COSV64121340; called by muse, mutect2, varscan2
- MYOM3 | c.253C>T p.L85= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100293795; called by muse, mutect2, varscan2
- NCAN | c.2928G>A p.G976= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as COSV99388282; called by muse, mutect2, varscan2
- NPR3 | c.165G>T p.V55= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99423836; called by mutect2, varscan2
- NRG1 | c.1128A>T p.V376= (on ENST00000405005 / NM_013964.5; = p.V381= on NM_013956.5) | Silent (SNP) | VAF 63/138 reads (46%) | catalogued as COSV99829478; called by muse, mutect2, varscan2
- NRXN1 | c.813C>G p.G271= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101280541, COSV101280866; called by muse, mutect2, varscan2
- NUP107 | c.333A>T p.A111= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99972053; called by muse, mutect2
- NVL | c.1656A>G p.E552= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99895137; called by muse, mutect2, varscan2
- OR1L1 | c.429T>C p.S143= (on ENST00000373686; = p.S93= on NM_001005236.3) | Silent (SNP) | VAF 81/233 reads (35%) | catalogued as rs571524691, COSV100542273; called by muse, mutect2, varscan2
- OR2T8 | c.96C>T p.I32= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs369748850; called by muse, mutect2, varscan2
- OR52H1 | c.333C>A p.V111= (on ENST00000322653; = p.V117= on NM_001005289.1) | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100497369; called by muse, mutect2, varscan2
- OSCAR | c.43C>T p.L15= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV52926969, COSV99500082; called by muse, mutect2, varscan2
- P2RY8 | c.1023T>A p.P341= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV101184192; called by muse, mutect2, varscan2
- PCDHB6 | c.837C>A p.A279= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99171187; called by muse, mutect2, varscan2
- PCDHGC4 | c.2436G>A p.G812= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1379023118, COSV99342225; called by muse, mutect2, varscan2
- PHYHIP | c.720G>T p.A240= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100395139; called by muse, mutect2, varscan2
- PKD1 | c.3132G>A p.L1044= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99239008; called by muse, mutect2, varscan2
- PKHD1L1 | c.2646T>C p.T882= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV101005699, COSV101006800; called by muse, mutect2, varscan2
- PLEKHA5 | c.645G>C p.L215= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100164727; called by muse, mutect2, varscan2
- PLEKHH1 | c.3168G>A p.L1056= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV100233467; called by muse, mutect2, varscan2
- POTEH | c.138T>A p.S46= | Silent (SNP) | VAF 104/583 reads (18%) | catalogued as COSV100625225; called by muse, varscan2
- PXDNL | c.2796C>T p.P932= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100686159; called by muse, mutect2, varscan2
- REP15 | c.9G>A p.Q3= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99945406; called by muse, mutect2
- RYR2 | c.798T>C p.A266= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1245793918, COSV100772779; called by muse, mutect2, varscan2
- RYR2 | c.8883G>A p.K2961= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1252809808, COSV100772781; called by muse, mutect2, varscan2
- SAMD4B | c.1629G>A p.Q543= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100080639; called by muse, mutect2, varscan2
- SCG3 | c.1356C>A p.I452= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs752841736, COSV99591191, COSV99591290; called by muse, mutect2, varscan2
- SCLY | c.489G>T p.L163= (on ENST00000651534; = p.L155= on NM_016510.7) | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- SELP | c.2199T>C p.H733= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV99741083; called by muse, mutect2, varscan2
- SLC22A2 | c.1443G>T p.T481= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs530891966, COSV100871047; called by muse, mutect2, varscan2
- SLC26A7 | c.1392C>G p.T464= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as COSV52590920, COSV99404299; called by muse, mutect2, varscan2
- SRCAP | c.9186C>A p.P3062= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99351287; called by muse, mutect2, varscan2
- TAFA2 | c.390C>G p.T130= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV101353913, COSV69186223; called by muse, mutect2, varscan2
- TM4SF5 | c.207G>T p.R69= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1315846693, COSV99564816; called by muse, mutect2, varscan2
- TMOD1 | c.808C>T p.L270= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99404177; called by muse, mutect2, varscan2
- TRAPPC11 | c.2061G>T p.V687= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100592039; called by muse, mutect2, varscan2
- TTN | c.69078C>A p.A23026= (on ENST00000591111; = p.A15602= on NM_003319.4) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100629010; called by muse, mutect2, varscan2
- WDR64 | c.1146C>A p.V382= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100843925, COSV63794001, COSV63800526; called by mutect2, varscan2
- XKR7 | c.1410G>C p.T470= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV101629225, COSV101629301; called by muse, mutect2, varscan2
- ZBED8 | c.930A>T p.L310= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV101283552; called by muse, mutect2, varscan2
- ZNF831 | c.1170C>A p.P390= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- ARPP19P1 | n.52G>A | RNA (SNP) | VAF 6/11 reads (55%) | catalogued as rs1394413592; called by muse, mutect2, varscan2
- C12orf77 | n.537A>T | RNA (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- FAM183BP | n.1156C>T | RNA (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- FRMPD2B | n.657C>T | RNA (SNP) | VAF 6/51 reads (12%) | called by mutect2, varscan2
- HSPG2 | c.575-612A>G | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- KCNK12 | c.*8523C>A | 3'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100010040; called by muse, mutect2, varscan2
- SNORD115-21 | n.75del | RNA (DEL) | VAF 80/212 reads (38%) | called by mutect2, pindel, varscan2
- USH1C | c.1646+1083C>T | Intron (SNP) | VAF 52/115 reads (45%) | catalogued as rs1403018876, COSV99141949; called by muse, mutect2, varscan2
- UVSSA | c.*8790C>A | 3'UTR (SNP) | VAF 122/376 reads (32%) | catalogued as rs532123027, COSV61348706; called by muse, varscan2
